Somatic mutation profile of tumor specimen TCGA-22-5472-01A (aliquot TCGA-22-5472-01A-01D-1632-08) from TCGA case TCGA-22-5472, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.0 years (24,482 days).
Specimen TCGA-22-5472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b88e642-da95-40bb-967b-d9d534d70d3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5472-11A (Solid Tissue Normal), aliquot TCGA-22-5472-11A-11D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9acd8b46-e076-4a5f-8f40-752c11f7632b

The open-access MAF lists 443 somatic variants for this specimen: 303 protein-altering or splice-affecting, 131 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 131, Nonsense Mutation 26, Splice Site 7, Intron 5, Frame Shift Del 4, Frame Shift Ins 2, In Frame Del 2, RNA 2, Splice Region 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA1 | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 34/54 reads (63%) | catalogued as rs1554049422, CM083069, COSV57191908; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-8_106del p.X33_splice | Splice Site (DEL) | VAF 35/91 reads (38%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- A2ML1 | c.2900C>G p.P967R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55292542; called by muse, mutect2, varscan2
- A4GNT | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52629201; called by muse, mutect2, varscan2
- ABCA13 | c.9287A>G p.H3096R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs200969547; called by muse, mutect2, varscan2
- AC013489.1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs778682836, COSV51551922; called by muse, mutect2, varscan2
- AC136428.1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV71169188; called by muse, mutect2, varscan2
- ACAN | c.5878G>T p.G1960C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61362551; called by muse, mutect2
- ADAM2 | c.1702A>T p.S568C | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV55863962; called by muse, mutect2, varscan2
- ADAMTS14 | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64603364; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV55001391; called by muse, mutect2, varscan2
- ALYREF | c.697A>G p.R233G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV58668674; called by muse, mutect2, varscan2
- ANK1 | c.5551G>T p.V1851L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55884687; called by muse, mutect2, varscan2
- ANKRD35 | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62910728; called by muse, mutect2, varscan2
- ARHGEF2 | c.1233G>T p.E411D (on ENST00000361247 / NM_001162383.2; = p.E383D on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.99); catalogued as COSV58112278; called by muse, mutect2, varscan2
- ATP10D | c.3675C>G p.I1225M | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV56707723, COSV56708851; called by muse, mutect2
- AZU1 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV52141395; called by muse, mutect2, varscan2
- BBS4 | c.930G>T p.L310F | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51438538; called by muse, mutect2, varscan2
- BCORL1 | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54398888; called by muse, mutect2, varscan2
- BFSP1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs372210205; called by muse, mutect2
- BTNL3 | c.93G>T p.L31F | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.71); catalogued as COSV61565101; called by muse, mutect2
- C10orf71 | c.1046G>T p.W349L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV60509047; called by muse, mutect2
- C2orf15 | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); catalogued as COSV56781977; called by muse, mutect2, varscan2
- C8orf58 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.495); catalogued as COSV51515505; called by muse, mutect2, varscan2
- CACNA1H | c.1015A>C p.N339H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61993924; called by muse, mutect2, varscan2
- CACTIN | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99698403; called by muse, mutect2, varscan2
- CCDC63 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV57529081; called by muse, mutect2, varscan2
- CCDC78 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV52402820; called by muse, mutect2, varscan2
- CCDC91 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60343882; called by muse, mutect2, varscan2
- CD2BP2 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59769047; called by muse, mutect2, varscan2
- CD5L | c.684C>G p.C228W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63822312; called by muse, mutect2, varscan2
- CDH2 | c.1597A>G p.R533G | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV52284029; called by muse, mutect2, varscan2
- CELF4 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV58456591; called by muse, mutect2, varscan2
- CENPN | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54729433; called by muse, mutect2, varscan2
- CEP250 | c.327G>T p.R109S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753546802, COSV61171042; called by muse, mutect2, varscan2
- CHD5 | c.2686G>T p.E896* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as COSV52417438; called by muse, mutect2, varscan2
- CHMP1B | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV52328954; called by muse, mutect2
- CITED2 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100863103; called by mutect2, varscan2
- CNTNAP2 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62179727, COSV62201657; called by muse, mutect2, varscan2
- COG5 | c.949-1G>T p.X317_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV51754675; called by muse, mutect2, varscan2
- COL11A2 | c.1808C>G p.P603R (on ENST00000341947 / NM_080680.3; = p.P496R on NM_080679.2) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59498337; called by muse, mutect2, varscan2
- COL13A1 | c.1775G>T p.G592V (on ENST00000398978 / NM_001130103.2; = p.G520V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62571219; called by muse, mutect2, varscan2
- COL21A1 | c.2609G>T p.G870V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55167317; called by muse, mutect2
- COL22A1 | c.3240C>A p.D1080E | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.995); catalogued as rs775736940, COSV57342872; called by muse, mutect2, varscan2
- COL2A1 | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61531675; called by muse, mutect2, varscan2
- COL9A3 | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV59653622; called by muse, mutect2, varscan2
- CPA1 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV50570836; called by muse, mutect2, varscan2
- CPD | c.2065G>T p.A689S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV56713784; called by muse, mutect2, varscan2
- CPED1 | c.1790A>T p.Y597F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs908301851, COSV60005009; called by muse, mutect2, varscan2
- CROCC | c.3469G>T p.E1157* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV65012864; called by muse, mutect2, varscan2
- CSE1L | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as COSV99521941; called by muse, mutect2
- CSMD3 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 40/154 reads (26%) | catalogued as COSV52214034; called by muse, mutect2, varscan2
- CSRNP3 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58780041; called by muse, mutect2, varscan2
- CYP7B1 | c.947C>A p.A316E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV100043022, COSV59590993; called by muse, mutect2, varscan2
- DCC | c.1865C>A p.P622Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59110301; called by muse, mutect2, varscan2
- DDX51 | c.1627C>A p.Q543K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.141); catalogued as COSV57958670; called by muse, mutect2, varscan2
- DENND2B | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs1300604844, COSV58204835; called by muse, mutect2, varscan2
- DENND4A | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV71266090; called by muse, mutect2, varscan2
- DGKI | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55956257; called by muse, mutect2, varscan2
- DGKI | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV55956274; called by muse, mutect2, varscan2
- DIS3L | c.1512C>A p.H504Q (on ENST00000319212 / NM_001143688.3; = p.H421Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59912927; called by muse, mutect2, varscan2
- DMAC2L | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV55413658; called by muse, mutect2, varscan2
- DMBT1 | c.3005G>T p.C1002F (on ENST00000338354 / NM_001377530.1; = p.C503F on NM_004406.3) | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV57547715; called by muse, mutect2
- DNAH2 | c.11580G>T p.M3860I | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV66721083; called by muse, mutect2, varscan2
- DNAJC13 | c.4087G>T p.G1363W | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99607024; called by muse, mutect2, varscan2
- DPP4 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1284790925, COSV62107503; called by muse, mutect2
- DPPA2 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 27/117 reads (23%) | catalogued as COSV72118140, COSV72118292; called by muse, mutect2, varscan2
- DPPA4 | c.74C>A p.S25* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV59511100, COSV59512264; called by muse, mutect2
- DSG1 | c.1380C>A p.Y460* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV57136582; called by muse, mutect2, varscan2
- DSG3 | c.2693G>T p.C898F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV57127212; called by muse, mutect2, varscan2
- DSG4 | c.912G>T p.L304F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as COSV57393102, COSV57396933; called by muse, mutect2, varscan2
- DTL | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV59182288; called by muse, mutect2, varscan2
- DYRK3 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65606607; called by muse, mutect2, varscan2
- EDC4 | c.3943C>T p.Q1315* | Nonsense Mutation (SNP) | VAF 62/200 reads (31%) | catalogued as COSV59303021; called by muse, mutect2, varscan2
- EEF1A2 | c.1202T>C p.I401T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.861); catalogued as COSV53206749; called by muse, mutect2, varscan2
- EIF5 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV53685738; called by muse, mutect2, varscan2
- ELMOD3 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59773379; called by muse, mutect2, varscan2
- EMILIN3 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60036965, COSV60037985; called by muse, mutect2, varscan2
- EMSY | c.1802C>A p.T601K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58262323; called by muse, mutect2
- ENPP2 | c.728A>G p.H243R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV50019233; called by muse, mutect2, varscan2
- ENTPD6 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV100737195, COSV61751798; called by muse, mutect2, varscan2
- EPHX2 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV66845140; called by muse, mutect2, varscan2
- ERVW-1 | c.481C>A p.H161N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV101423823; called by muse, mutect2, varscan2
- ETV2 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99386949; called by muse, mutect2, varscan2
- FANCB | c.2527G>T p.A843S | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60760385; called by muse, mutect2, varscan2
- FAT1 | c.12791C>A p.S4264* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV71673914, COSV71674717; called by muse, mutect2, varscan2
- FAT1 | c.9068G>T p.C3023F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71674718, COSV71675879; called by muse, mutect2, varscan2
- FAT1 | c.3574A>T p.K1192* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV71674719; called by muse, mutect2
- FBN3 | c.3219C>A p.D1073E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs142033402, COSV54463928; called by muse, mutect2
- FBXL16 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs11555893, COSV60964806; called by muse, mutect2, varscan2
- FCN2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.697); catalogued as COSV52477434; called by muse, mutect2
- FCRL5 | c.1124-1G>T p.X375_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as rs1456987386, COSV62515890; called by muse, mutect2
- FGF2 | c.654G>C p.M218I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV52650793; called by muse, mutect2, varscan2
- FKBP14 | c.115C>A p.H39N | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.131); catalogued as COSV51651999; called by muse, mutect2, varscan2
- FLII | c.3633G>C p.Q1211H | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as COSV57498809; called by muse, mutect2
- FNDC7 | c.708G>C p.L236F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs778743628, COSV54754864; called by muse, mutect2
- FOXD4L1 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as COSV52074933; called by muse, mutect2, varscan2
- FRMPD2 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV59719264; called by muse, mutect2, varscan2
- FTSJ3 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as rs941087293, COSV59562880; called by muse, mutect2, varscan2
- FYN | c.1376T>C p.L459P | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57616194; called by muse, mutect2, varscan2
- FZD3 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53536139; called by muse, mutect2, varscan2
- GAB3 | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV65819918; called by muse, mutect2, varscan2
- GABRB1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54986649, COSV54999927; called by muse, mutect2, varscan2
- GAD2 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as COSV52151431; called by muse, mutect2, varscan2
- GALNT1 | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52453142, COSV52454732; called by muse, mutect2, varscan2
- GANC | c.1562C>A p.P521Q | Missense Mutation (SNP) | VAF 44/120 reads (37%) | PolyPhen possibly damaging (0.902); catalogued as COSV58809619; called by muse, mutect2, varscan2
- GFOD2 | c.857C>A p.A286E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV52057923, COSV52058456; called by muse, mutect2, varscan2
- GJC3 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs1330895576, COSV57210458; called by muse, mutect2, varscan2
- GLB1L2 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV60279138; called by muse, mutect2, varscan2
- GNA14 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs748873215, COSV59025122; called by muse, mutect2, varscan2
- GP9 | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV56624309; called by muse, mutect2
- GPATCH8 | c.4228C>A p.Q1410K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59195561; called by muse, mutect2, varscan2
- GRIN2B | c.4195C>A p.H1399N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV74206437; called by muse, mutect2, varscan2
- GRIN2D | c.589C>A p.H197N | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV54379978; called by muse, mutect2, varscan2
- GRM3 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs766672277, COSV64473965; called by muse, mutect2, varscan2
- HADHA | c.78C>A p.C26* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV66106206, COSV66107758; called by muse, mutect2, varscan2
- HARS1 | c.1040C>A p.A347E | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.04); catalogued as COSV56907453; called by muse, mutect2, varscan2
- HDAC9 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67776022; called by muse, mutect2, varscan2
- HIP1 | c.2921C>A p.T974K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV61187538; called by muse, mutect2
- HNF4A | c.104C>A p.T35K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV57384718; called by muse, mutect2, varscan2
- IARS2 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV56960737; called by muse, mutect2, varscan2
- ICE1 | c.5185G>T p.G1729C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56827281; called by muse, mutect2
- IFITM2 | c.103C>A p.H35N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); catalogued as COSV67714729; called by muse, mutect2, varscan2
- IGF2 | c.631C>G p.H211D (on ENST00000434045 / NM_001127598.3; = p.H155D on NM_000612.6) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV56099736; called by muse, mutect2, varscan2
- IL1RAPL1 | c.21C>A p.H7Q | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV56271470; called by muse, mutect2, varscan2
- ITGA2 | c.1207G>T p.G403C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV56861491; called by muse, mutect2, varscan2
- ITGA8 | c.1942G>T p.V648F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV65230555; called by muse, mutect2, varscan2
- KALRN | c.7210C>A p.H2404N (on ENST00000360013 / NM_001024660.4; = p.H707N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.199); catalogued as rs1328607696, COSV52258675; called by muse, mutect2, varscan2
- KBTBD4 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as COSV58597355; called by muse, mutect2, varscan2
- KCNJ1 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs868519471, COSV60662087; called by muse, mutect2, varscan2
- KLHDC2 | c.811C>A p.H271N | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53587582; called by muse, mutect2, varscan2
- KMT5B | c.2618C>A p.S873* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV58567168; called by muse, mutect2, varscan2
- KRT2 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs777351947, COSV59011037; called by muse, mutect2
- KRT82 | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.117); catalogued as COSV57786357; called by muse, mutect2, varscan2
- KRTAP13-2 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.851); catalogued as COSV67762077; called by muse, mutect2, varscan2
- KRTAP19-3 | c.6C>A p.S2R | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV61854845; called by muse, mutect2, varscan2
- KSR2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs548971268, COSV100351462, COSV60366465, COSV60384960; called by muse, mutect2, varscan2
- LAMA1 | c.7450G>A p.E2484K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV67539041; called by muse, mutect2, varscan2
- LAMB4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV52722048; called by muse, mutect2, varscan2
- LAMC2 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV51456754; called by muse, mutect2, varscan2
- LIFR | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.041); catalogued as COSV99663816; called by muse, mutect2
- LILRB4 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 51/193 reads (26%) | catalogued as COSV54406281; called by muse, mutect2, varscan2
- LILRB5 | c.1637C>G p.A546G (on ENST00000449561 / NM_001081442.3; = p.A545G on NM_006840.5) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.755); catalogued as COSV60258517; called by muse, mutect2, varscan2
- LRFN1 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.379); catalogued as COSV50455544; called by muse, mutect2, varscan2
- LRIG2 | c.3076G>T p.E1026* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV63162667; called by muse, mutect2, varscan2
- LRP1 | c.3057G>T p.Q1019H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54515128; called by muse, mutect2, varscan2
- LRP6 | c.2206G>T p.G736W | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53789312; called by muse, mutect2, varscan2
- LRRK2 | c.7507G>T p.E2503* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV54157198; called by muse, mutect2, varscan2
- MAGEC2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs755701847, COSV55999711; called by muse, mutect2, varscan2
- MAPK7 | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV55190842; called by muse, mutect2, varscan2
- MDH1B | c.1030G>C p.V344L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV65590243; called by muse, mutect2, varscan2
- MDN1 | c.5548G>T p.E1850* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV65523465; called by muse, mutect2, varscan2
- MDN1 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV65523470; called by muse, mutect2, varscan2
- MUC3A | c.8477C>T p.T2826I | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60217943; called by muse, mutect2, varscan2
- MUS81 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57260464; called by muse, mutect2, varscan2
- MYH15 | c.4144C>A p.Q1382K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV56312828; called by muse, mutect2, varscan2
- MYO18B | c.438G>C p.R146S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV59137929; called by muse, mutect2, varscan2
- MYO7B | c.3424C>A p.P1142T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV67348696; called by muse, mutect2, varscan2
- MYO7B | c.3425C>A p.P1142Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67348700; called by muse, mutect2, varscan2
- MYO9B | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68280136; called by muse, mutect2, varscan2
- NAT10 | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV57664514; called by mutect2, varscan2
- NAT16 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs774424411, COSV55864891; called by muse, mutect2, varscan2
- NCOA6 | c.1900C>A p.Q634K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV62864928, COSV62866390; called by muse, mutect2, varscan2
- NEB | c.10750G>T p.A3584S | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV51427194; called by muse, mutect2, varscan2
- NECTIN3 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60551945, COSV60552432; called by muse, mutect2, varscan2
- NF1 | c.7063-2A>G p.X2355_splice (on ENST00000358273 / NM_001042492.3; = p.X2334_splice on NM_000267.3) | Splice Site (SNP) | VAF 22/41 reads (54%) | catalogued as CS076640, COSV62198535, COSV62204118; called by muse, mutect2, varscan2
- NFATC1 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs773206226, COSV53702662; called by muse, mutect2, varscan2
- NFATC2IP | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV57910486; called by muse, mutect2, varscan2
- NTNG2 | c.652C>A p.R218S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762394861, COSV62364031, COSV62367374; called by muse, mutect2, varscan2
- NUDT6 | c.281G>T p.W94L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58646574; called by muse, mutect2, varscan2
- OR10A5 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV55054663; called by muse, mutect2, varscan2
- OR1J4 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV61589830, COSV61589956; called by muse, mutect2, varscan2
- OR51B5 | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56176375; called by muse, mutect2, varscan2
- OR52B2 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as COSV73209437; called by muse, mutect2, varscan2
- OTOA | c.1617G>T p.R539S (on ENST00000286149; = p.R525S on NM_144672.4) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV53757109; called by muse, mutect2, varscan2
- P3H1 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV52534684; called by muse, mutect2, varscan2
- PAPLN | c.2145G>T p.E715D (on ENST00000554301; = p.E688D on NM_173462.4) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as COSV53719473; called by muse, mutect2, varscan2
- PBXIP1 | c.408A>G p.A136= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as COSV63777329; called by muse, mutect2, varscan2
- PCDH8 | c.182C>A p.T61K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs1415445029, COSV58813325; called by muse, mutect2, varscan2
- PCDHGB5 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV53968918; called by muse, mutect2, varscan2
- PCLO | c.2609C>A p.P870Q | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV61642742; called by muse, mutect2, varscan2
- PCYOX1 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52476834; called by muse, mutect2, varscan2
- PDP2 | c.116G>T p.W39L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV61240771; called by muse, mutect2, varscan2
- PEG3 | c.931C>A p.H311N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55630929, COSV55637282; called by muse, mutect2, varscan2
- PEX5L | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs146906651; called by muse, mutect2, varscan2
- PHRF1 | c.1414C>A p.H472N (on ENST00000264555 / NM_001286581.2; = p.H471N on NM_020901.4) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99199828; called by muse, mutect2, varscan2
- PLXNA4 | c.4096C>A p.L1366M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58135446; called by muse, mutect2, varscan2
- PMS1 | c.1998C>A p.H666Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59717217; called by muse, mutect2, varscan2
- PNPT1 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.157); catalogued as COSV53177960; called by muse, mutect2, varscan2
- PPP2R5B | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51210671; called by muse, mutect2, varscan2
- PRB1 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs754332219, COSV53704400; called by muse, mutect2, varscan2
- PRPF8 | c.3416G>T p.R1139L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs980715336, COSV59264326, COSV59265117; called by muse, mutect2, varscan2
- PRSS22 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50722123; called by muse, mutect2
- PRTG | c.3443C>A p.P1148H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV66838631; called by muse, mutect2, varscan2
- PTK2 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61786537, COSV61787485; called by muse, mutect2, varscan2
- PTPDC1 | c.722C>A p.T241N (on ENST00000375360 / NM_177995.3; = p.T293N on NM_152422.4) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV56624024; called by muse, mutect2
- PTPRU | c.1934A>T p.D645V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV60529994; called by muse, mutect2
- PXDNL | c.2989G>T p.V997F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1208587091, COSV62490487; called by muse, mutect2, varscan2
- RAB14 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as COSV65788465; called by muse, mutect2, varscan2
- RALY | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55781894; called by muse, mutect2, varscan2
- RANBP10 | c.1837G>T p.A613S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV58158686; called by muse, mutect2, varscan2
- RASAL2 | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV62716109; called by muse, mutect2, varscan2
- RASGRP4 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV53096132; called by muse, mutect2
- REPIN1 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68292490; called by muse, mutect2, varscan2
- RFPL2 | c.850G>T p.G284* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV50712148; called by muse, mutect2
- RFX3 | c.1523C>A p.A508E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56518146; called by muse, mutect2, varscan2
- ROS1 | c.6628A>T p.R2210* | Nonsense Mutation (SNP) | VAF 40/133 reads (30%) | catalogued as rs1278629013, COSV63856652; called by muse, mutect2
- RPTN | c.1665G>T p.Q555H | Missense Mutation (SNP) | VAF 215/665 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV60167674; called by muse, mutect2, varscan2
- RRP7A | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59899775; called by muse, mutect2, varscan2
- RYR2 | c.13036G>T p.G4346W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV63692104; called by muse, mutect2, varscan2
- SCN5A | c.3245T>G p.V1082G (on ENST00000333535 / NM_198056.3; = p.V1081G on NM_000335.5) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as COSV61128320; called by muse, mutect2, varscan2
- SFTA2 | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100764473; called by muse, mutect2
- SH2D4B | c.763A>T p.M255L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs370698042, COSV57896979; called by muse, mutect2, varscan2
- SIN3A | c.1274G>T p.C425F | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.096); catalogued as COSV64583519; called by muse, mutect2
- SIRT4 | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52541210; called by muse, mutect2, varscan2
- SLC17A6 | c.1720A>T p.S574C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV54137616, COSV54137671; called by muse, mutect2, varscan2
- SLC26A9 | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536238; called by muse, mutect2, varscan2
- SLC28A1 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.573); catalogued as COSV54480745; called by muse, mutect2, varscan2
- SLC4A1 | c.2262G>T p.Q754H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV52261024; called by muse, mutect2, varscan2
- SLC6A16 | c.1308C>A p.Y436* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV60028449; called by muse, mutect2, varscan2
- SLC6A5 | c.2039G>T p.C680F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54228160; called by muse, mutect2, varscan2
- SLX4 | c.2813C>A p.A938E | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53565166; called by muse, mutect2, varscan2
- SNIP1 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56165716; called by muse, mutect2, varscan2
- SNX29 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs760782009, COSV60062626; called by muse, mutect2, varscan2
- SORCS3 | c.1875C>A p.H625Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.083); catalogued as COSV63813924; called by muse, mutect2, varscan2
- SPAG17 | c.1703C>A p.P568Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60461284; called by muse, mutect2, varscan2
- SPTBN4 | c.4258G>T p.A1420S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.056); catalogued as COSV58952182; called by muse, mutect2, varscan2
- STAR | c.276C>G p.N92K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV52417741; called by muse, mutect2, varscan2
- STIM1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV56156477; called by muse, mutect2, varscan2
- STMN3 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV64246915; called by muse, mutect2
- STS | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54269166; called by muse, mutect2, varscan2
- STX5 | c.808G>C p.A270P | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53680071; called by muse, mutect2, varscan2
- SULT1A2 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV57682127; called by muse, mutect2, varscan2
- SV2C | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59222334; called by muse, mutect2, varscan2
- SWT1 | c.1101G>T p.M367I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62256181, COSV62258626; called by muse, mutect2, varscan2
- TAB1 | c.1178C>A p.P393Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53371862; called by muse, mutect2, varscan2
- TBX3 | c.966G>T p.M322I (on ENST00000257566 / NM_016569.4; = p.M302I on NM_005996.4) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV57472360, COSV57472756; called by muse, mutect2, varscan2
- TCN2 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53191876; called by muse, mutect2, varscan2
- TCTA | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV55534131; called by muse, mutect2, varscan2
- TEDDM1 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs112817733, COSV62380553; called by muse, mutect2, varscan2
- TELO2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs926165620, COSV51978898; called by muse, mutect2, varscan2
- TENM1 | c.3140C>A p.S1047* | Nonsense Mutation (SNP) | VAF 44/58 reads (76%) | catalogued as COSV64434851; called by muse, mutect2, varscan2
- TEX2 | c.1739G>T p.R580I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV51982443, COSV51983193; called by muse, mutect2, varscan2
- TGM5 | c.1783C>T p.R595C (on ENST00000220420 / NM_201631.4; = p.R513C on NM_004245.4) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs777999621, COSV55010503; called by muse, mutect2, varscan2
- THOC5 | c.355-1G>T p.X119_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV63799285; called by muse, mutect2, varscan2
- THSD7B | c.2743C>A p.L915I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV55700991, COSV99753563; called by muse, mutect2, varscan2
- TLCD3B | c.294C>A p.H98Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV54227417; called by muse, mutect2, varscan2
- TM4SF1 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV59525063; called by muse, mutect2, varscan2
- TMCC3 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV54155212; called by muse, mutect2, varscan2
- TMED5 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64757150; called by muse, mutect2, varscan2
- TMEM120A | c.218C>A p.P73Q | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV50390206; called by muse, mutect2, varscan2
- TMEM132B | c.2234G>T p.W745L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV54757351; called by muse, mutect2, varscan2
- TMEM143 | c.1378T>C p.*460Rext*14 | Nonstop Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV53157062; called by muse, mutect2
- TMEM176B | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.778); catalogued as COSV50244194; called by muse, mutect2, varscan2
- TMPRSS12 | c.934T>G p.W312G | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV68256561; called by muse, mutect2, varscan2
- TNRC18 | c.8156A>T p.K2719M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as COSV60308091; called by muse, mutect2, varscan2
- TPST1 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59177899; called by muse, mutect2, varscan2
- TRAF5 | c.225A>T p.L75F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.955); catalogued as COSV54823078; called by muse, mutect2, varscan2
- TRPA1 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV51564713; called by muse, mutect2, varscan2
- TSSC4 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200528668, COSV50158752; called by muse, mutect2, varscan2
- TTC30A | c.1828C>A p.Q610K | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV63101737; called by muse, mutect2
- TTN | c.59432C>A p.P19811Q (on ENST00000591111; = p.P12387Q on NM_003319.4) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | PolyPhen probably damaging (0.952); catalogued as COSV60137415; called by muse, mutect2, varscan2
- TTN | c.12667G>T p.V4223L (on ENST00000591111; = p.V4177L on NM_003319.4) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV60137479; called by muse, mutect2, varscan2
- TUT4 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57115607; called by muse, mutect2, varscan2
- TXN2 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53397741; called by muse, mutect2, varscan2
- UBR7 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50149107, COSV50149972; called by muse, mutect2, varscan2
- UBXN8 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV55665008; called by muse, mutect2, varscan2
- UCP2 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60104935; called by muse, mutect2, varscan2
- USH2A | c.5468C>G p.A1823G | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV56387014; called by muse, mutect2, varscan2
- USP37 | c.1472+1G>A p.X491_splice | Splice Site (SNP) | VAF 12/41 reads (29%) | catalogued as rs1559185420, COSV51444310; called by muse, mutect2, varscan2
- UTRN | c.9132G>T p.L3044F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62304558; called by muse, mutect2, varscan2
- VCL | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.319); catalogued as COSV53010865; called by muse, mutect2, varscan2
- VWA5A | c.1421A>T p.H474L | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV64413135; called by muse, mutect2, varscan2
- WDR20 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54473147; called by muse, mutect2, varscan2
- WDR59 | c.1817G>T p.R606L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV50936987; called by muse, mutect2
- WDR70 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.191); catalogued as COSV54275246; called by muse, mutect2, varscan2
- WDR90 | c.1286C>A p.A429E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV53471309; called by muse, mutect2, varscan2
- ZFHX3 | c.4225G>T p.A1409S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51722832; called by muse, mutect2, varscan2
- ZFP57 | c.1448T>A p.L483H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65305872, COSV65306342; called by muse, mutect2, varscan2
- ZNF248 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV61997958; called by muse, mutect2, varscan2
- ZNF266 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV63222397; called by muse, mutect2, varscan2
- ZNF296 | c.451C>G p.R151G | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55514627, COSV55516877; called by muse, mutect2, varscan2
- ZNF335 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV59817259; called by muse, mutect2, varscan2
- ZNF451 | c.1889G>C p.S630T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1212928635, COSV62598148; called by muse, mutect2, varscan2
- ZNF548 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV60241218; called by muse, mutect2, varscan2
- ZNF575 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV58564749; called by muse, mutect2
- ZNF804A | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs780213451, COSV100169832, COSV56446311; called by muse, mutect2, varscan2
- ZNF804A | c.2244G>T p.M748I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56454165; called by muse, mutect2, varscan2
- ZNFX1 | c.5709C>A p.D1903E | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV65598703; called by muse, mutect2, varscan2
- ZSCAN16 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100481475, COSV61258858; called by muse, mutect2
- ZW10 | c.560G>T p.W187L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV52317250; called by muse, mutect2, varscan2
- AKAP4 | c.1709G>T p.C570F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.057); called by muse, mutect2
- CLIP4 | c.1030del p.A344Hfs*6 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- ELP4 | c.88del p.Q30Rfs*9 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- FSIP2 | c.16829dup p.K5611Efs*3 | Frame Shift Ins (INS) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1010A>T p.K337M | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPNMB | c.735_737del p.K245del | In Frame Del (DEL) | VAF 27/109 reads (25%) | called by pindel, varscan2
- ILVBL | c.1285_1287del p.K429del | In Frame Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.954C>A p.N318K | Missense Mutation (SNP) | VAF 110/329 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LPAR2 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- PTPN14 | c.3086dup p.H1030Afs*47 | Frame Shift Ins (INS) | VAF 43/257 reads (17%) | called by mutect2, pindel, varscan2
- U2SURP | c.947del p.R316Kfs*11 | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel*, varscan2
- VPS13D | c.8890_8891del p.T2964Pfs*2 | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | called by pindel, varscan2
- AASDH | c.3054A>C p.S1018= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV52707554; called by muse, mutect2, varscan2
- ABCA13 | c.8520C>A p.S2840= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV71290201; called by muse, mutect2, varscan2
- ABCA3 | c.4107G>T p.L1369= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV104400115, COSV57055325; called by muse, mutect2, varscan2
- ABCA7 | c.3984C>A p.A1328= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV54031786; called by muse, mutect2, varscan2
- ADCY5 | c.813G>T p.L271= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV71901464; called by muse, mutect2, varscan2
- ALDH1A1 | c.1098C>A p.A366= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV52792051; called by muse, mutect2
- APOD | c.522C>A p.V174= | Silent (SNP) | VAF 7/181 reads (4%) | catalogued as COSV58402185; called by muse, mutect2
- ARHGEF10L | c.1737C>A p.A579= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV51434507; called by muse, mutect2, varscan2
- BACH2 | c.1425C>A p.P475= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1226848014, COSV57596866; called by muse, mutect2, varscan2
- BAG3 | c.1305G>T p.L435= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV64842149; called by muse, mutect2
- BRCA2 | c.7461C>A p.A2487= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV66455801; called by muse, mutect2, varscan2
- C1orf74 | c.138G>T p.V46= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV50554082; called by muse, mutect2
- C6orf15 | c.477C>A p.A159= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV52538675; called by muse, mutect2, varscan2
- CAPG | c.417C>G p.L139= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV55707679; called by muse, mutect2, varscan2
- CCDC114 | c.1047C>A p.R349= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV59557139; called by muse, mutect2, varscan2
- CCDC157 | c.2253C>A p.P751= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV53176318; called by muse, mutect2, varscan2
- CDC37L1 | c.282C>A p.A94= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV67866098; called by muse, mutect2, varscan2
- CDH18 | c.1803T>C p.H601= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV56931555; called by muse, mutect2, varscan2
- CDH23 | c.7431C>A p.A2477= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56471189; called by muse, mutect2
- CELF5 | c.1017C>A p.A339= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1381253909, COSV53012564; called by muse, mutect2, varscan2
- CEP63 | c.1581G>T p.L527= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV59677043; called by muse, mutect2, varscan2
- CHST11 | c.369G>T p.V123= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV57989434; called by muse, mutect2, varscan2
- CLEC16A | c.618C>A p.A206= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV68500266; called by muse, mutect2
- CLSTN1 | c.2496G>T p.V832= (on ENST00000377298 / NM_001009566.3; = p.V822= on NM_014944.4) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV63129513; called by muse, mutect2, varscan2
- CSPG4 | c.1317G>T p.V439= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57896883; called by muse, mutect2, varscan2
- CTLA4 | c.45G>T p.L15= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV55592502; called by muse, mutect2, varscan2
- CTNND2 | c.2691C>A p.L897= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV58877132, COSV58898119; called by muse, mutect2, varscan2
- DES | c.783G>A p.V261= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV64660519; called by muse, mutect2
- DSG3 | c.2922C>A p.G974= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs1403478471, COSV57127223; called by muse, mutect2, varscan2
- DYNC1H1 | c.8316C>A p.A2772= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV64138221; called by muse, mutect2
- EN1 | c.396C>A p.A132= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV54631716; called by muse, mutect2
- EPHA2 | c.2547C>A p.L849= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV64453498; called by muse, mutect2, varscan2
- ERN2 | c.744G>T p.L248= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV56834747; called by muse, mutect2, varscan2
- FAS | c.474A>T p.T158= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV58239129; called by muse, mutect2, varscan2
- FBXL16 | c.810G>T p.L270= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV60964801; called by muse, mutect2, varscan2
- FCRLB | c.1155G>T p.L385= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV61059984; called by muse, mutect2, varscan2
- FGA | c.426G>A p.K142= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV57397337; called by muse, mutect2, varscan2
- FNDC1 | c.2421G>T p.T807= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV51940488, COSV51944638; called by muse, mutect2
- FOXB1 | c.918C>A p.A306= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV68526055; called by muse, mutect2
- FYN | c.1377G>T p.L459= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV57616179; called by muse, mutect2, varscan2
- FZD7 | c.1128C>A p.A376= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV53810057; called by muse, mutect2
- G6PC | c.678G>T p.L226= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV53831294; called by muse, mutect2, varscan2
- GDPD3 | c.300G>T p.V100= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV53774274; called by muse, mutect2, varscan2
- GPM6A | c.303G>T p.V101= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV54547544; called by muse, mutect2, varscan2
- GPR137 | c.1101C>A p.P367= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs746374868, COSV100464137; called by muse, mutect2, varscan2
- GPR142 | c.678G>T p.V226= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV59519671; called by muse, mutect2, varscan2
- GPR176 | c.778C>A p.R260= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs768107128, COSV54445821; called by muse, mutect2, varscan2
- HRNR | c.6588C>A p.S2196= | Silent (SNP) | VAF 26/430 reads (6%) | catalogued as COSV100913506, COSV64259388; called by muse, mutect2
- IGFN1 | c.3345G>T p.V1115= (on ENST00000295591 / NM_001367841.1; = p.V3572= on NM_001164586.2) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs377163692; called by muse, mutect2, varscan2
- IGHV3-38 | c.219T>C p.G73= | Silent (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1437G>C p.G479= (on ENST00000538872 / NM_001170738.2; = p.G176= on NM_015232.1) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV58286320; called by muse, varscan2
- ITGB7 | c.2226G>T p.L742= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV57239109; called by muse, mutect2, varscan2
- ITPR3 | c.2667G>T p.L889= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100967214; called by muse, mutect2
- KCNK16 | c.396C>A p.G132= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV64678420; called by muse, mutect2, varscan2
- KIAA1217 | c.1923C>A p.A641= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV56818347; called by muse, mutect2
- KIR3DL1 | c.207C>A p.P69= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV58492319; called by muse, mutect2, varscan2
- KLHL6 | c.730C>A p.R244= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100384491, COSV58065881; called by muse, mutect2, varscan2
- KRT16 | c.105G>T p.L35= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1440582975, COSV56968520; called by muse, mutect2, varscan2
- KRT74 | c.291G>T p.V97= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV59772054; called by muse, mutect2, varscan2
- LAMA3 | c.9945C>A p.V3315= (on ENST00000313654 / NM_198129.4; = p.V1706= on NM_000227.6) | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV52536860; called by muse, mutect2, varscan2
- LAMA5 | c.10410C>A p.G3470= | Silent (SNP) | VAF 2/20 reads (10%) | catalogued as COSV53362655, COSV53373353; called by muse, mutect2
- LIPC | c.1197G>T p.T399= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100134810, COSV54423760; called by muse, mutect2, varscan2
- LNPK | c.225C>A p.A75= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99770057; called by muse, mutect2, varscan2
- LRRC29 | c.429C>A p.G143= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV58527514; called by muse, mutect2, varscan2
- LRRK1 | c.4431C>A p.S1477= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV52615759; called by muse, mutect2, varscan2
- LTBP1 | c.1581T>A p.P527= (on ENST00000404816 / NM_206943.4; = p.P201= on NM_000627.4) | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs774180212, COSV63190108; called by muse, mutect2, varscan2
- LTBP4 | c.1641C>A p.G547= (on ENST00000308370 / NM_001042544.1; = p.G510= on NM_003573.2) | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV52583759; called by muse, mutect2, varscan2
- MAP3K9 | c.2163C>A p.P721= (on ENST00000554752 / NM_001284230.1; = p.P735= on NM_033141.4) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV67121779; called by muse, mutect2, varscan2
- MDGA1 | c.2442G>T p.L814= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV51797367; called by muse, mutect2, varscan2
- MED1 | c.4728G>T p.V1576= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV56125928; called by muse, mutect2, varscan2
- MICAL3 | c.4302C>T p.S1434= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV71588625; called by muse, mutect2
- MMS22L | c.1296G>A p.K432= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV51522302; called by muse, mutect2, varscan2
- MYLK4 | c.810C>A p.L270= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as COSV51143594, COSV51153944; called by muse, mutect2, varscan2
- NAALADL1 | c.1704G>T p.V568= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV60524500; called by muse, mutect2, varscan2
- NAF1 | c.132A>G p.L44= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs939072520, COSV56804716; called by muse, mutect2, varscan2
- NCK1 | c.525G>T p.L175= | Silent (SNP) | VAF 44/208 reads (21%) | catalogued as rs1410486063, COSV56637988; called by muse, mutect2, varscan2
- NEB | c.10749G>T p.L3583= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as COSV51427211; called by muse, mutect2, varscan2
- NMNAT2 | c.345C>A p.S115= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV54269281, COSV54272084; called by muse, mutect2
- NOL9 | c.1284C>A p.P428= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV66626309; called by muse, mutect2
- NPC1L1 | c.3084C>A p.G1028= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs778564748, COSV56926452; called by muse, mutect2, varscan2
- NPR1 | c.1713T>C p.R571= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV64117727; called by muse, mutect2, varscan2
- NTRK3 | c.1008G>A p.L336= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV58127652; called by muse, mutect2, varscan2
- OR2T1 | c.171C>A p.P57= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as COSV63542252, COSV63542427; called by muse, mutect2, varscan2
- OR2Y1 | c.495C>A p.A165= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV57136780, COSV57137976; called by muse, mutect2, varscan2
- OR52K1 | c.153C>A p.I51= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV56903941, COSV56904340; called by muse, mutect2, varscan2
- OR56A3 | c.714G>T p.V238= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as COSV61569365; called by muse, mutect2, varscan2
- OSMR | c.1563C>A p.V521= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57086639; called by muse, mutect2, varscan2
- PAPLN | c.651T>C p.A217= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV53719460; called by muse, mutect2, varscan2
- PCDHB11 | c.1227G>T p.L409= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs781922915, COSV61312320; called by muse, mutect2, varscan2
- PDE1A | c.1089C>T p.H363= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs375806421, COSV59526375; called by muse, mutect2, varscan2
- PI4KA | c.2913G>T p.L971= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as rs1202827066, COSV55413996; called by muse, mutect2, varscan2
- PKP4 | c.624C>A p.A208= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV67677796; called by muse, mutect2, varscan2
- PLCB1 | c.378G>T p.V126= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV62056637; called by muse, mutect2, varscan2
- PLXNB2 | c.3183T>G p.P1061= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV63782516; called by muse, mutect2
- POM121C | c.2976C>A p.S992= (on ENST00000607367; = p.S750= on NM_001099415.3) | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV57546686; called by muse, mutect2, varscan2
- PRAMEF12 | c.1026G>T p.L342= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs201412674, COSV63215708; called by muse, mutect2, varscan2
- PRC1 | c.783C>A p.A261= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV62695754; called by muse, mutect2, varscan2
- PROM2 | c.1131G>T p.V377= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV58298353, COSV58298962; called by muse, mutect2, varscan2
- PRPH | c.1095G>T p.L365= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV57678884; called by muse, mutect2, varscan2
- PSD | c.1959G>T p.L653= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV50047630; called by muse, mutect2, varscan2
- PTGES2 | c.879C>G p.L293= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV52968690; called by muse, mutect2, varscan2
- PTK7 | c.2826A>G p.R942= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV57849373; called by muse, mutect2, varscan2
- PTPRT | c.2013C>A p.A671= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV61991063; called by muse, mutect2, varscan2
- PURG | c.327G>T p.L109= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV53301957; called by muse, mutect2, varscan2
- RAB38 | c.54G>T p.L18= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV54713680; called by muse, mutect2, varscan2
- RABL3 | c.12G>T p.L4= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV52204877; called by muse, mutect2, varscan2
- RBM15 | c.2283C>A p.S761= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV63923717; called by muse, mutect2, varscan2
- RPL10 | c.96C>A p.R32= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV50010482; called by muse, mutect2
- SDR42E1 | c.259C>A p.R87= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV61094545, COSV61094642; called by muse, mutect2, varscan2
- SEPTIN1 | c.1188G>A p.K396= (on ENST00000321367; = p.K349= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV58442619; called by muse, mutect2
- SFRP1 | c.195G>T p.L65= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV55174847; called by muse, mutect2, varscan2
- SIX4 | c.105G>T p.V35= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV53670231; called by muse, mutect2
- SLC16A6 | c.1242C>A p.G414= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV59177904; called by muse, mutect2, varscan2
- SNRNP200 | c.4252C>T p.L1418= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV60490840; called by muse, mutect2, varscan2
- SOX8 | c.867G>T p.L289= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV53509713; called by muse, mutect2
- STAG3 | c.660C>A p.L220= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV57931578; called by muse, mutect2, varscan2
- STAU2 | c.1437C>A p.A479= (on ENST00000524300 / NM_001164380.2; = p.A447= on NM_014393.2) | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV63308956; called by muse, mutect2, varscan2
- TAP2 | c.276C>A p.A92= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV66487958; called by muse, mutect2, varscan2
- TAPBP | c.30G>T p.V10= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV56470484; called by muse, mutect2, varscan2
- TARS3 | c.613C>T p.L205= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV60108469; called by muse, mutect2, varscan2
- TMEM30B | c.777G>T p.L259= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV63133736; called by muse, mutect2
- TNS3 | c.1227G>T p.L409= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2
- TRIM67 | c.1387C>T p.L463= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV64158031, COSV64159138; called by muse, mutect2
- TRIO | c.1851A>G p.A617= | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as COSV60086003; called by muse, mutect2, varscan2
- UBXN6 | c.864G>T p.L288= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56673022; called by muse, mutect2, varscan2
- VSIG4 | c.750C>A p.P250= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV66074046; called by muse, mutect2, varscan2
- WDR20 | c.1119C>A p.G373= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV54470517, COSV54473156; called by muse, mutect2, varscan2
- YOD1 | c.687C>A p.S229= | Silent (SNP) | VAF 67/202 reads (33%) | catalogued as COSV60006509; called by muse, mutect2, varscan2
- YWHAE | c.39G>T p.L13= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs748149659, COSV51983250; called by muse, mutect2, varscan2
- ZBTB48 | c.1686G>T p.V562= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV66553683; called by muse, mutect2, varscan2
- ZCCHC3 | c.909G>T p.L303= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV66643415; called by muse, mutect2, varscan2
- AMDHD2 | c.*1179G>T | 3'UTR (SNP) | VAF 13/31 reads (42%) | catalogued as COSV53551181; called by muse, mutect2, varscan2
- BMP1 | c.2107+1621C>T | Intron (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100109345; called by muse, varscan2
- FAM221B | c.743-1518C>A | Intron (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- MIR519E | n.58C>T | RNA (SNP) | VAF 10/35 reads (29%) | catalogued as rs778834695; called by muse, mutect2, varscan2
- NLRP7 | c.2810+2811G>T | Intron (SNP) | VAF 28/125 reads (22%) | catalogued as COSV100052219; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100157692 T>A | 3'Flank (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- SNORD115-30 | n.58G>T | RNA (SNP) | VAF 54/186 reads (29%) | catalogued as rs768241149; called by muse, mutect2, varscan2
- TTN | c.34264+4783C>T | Intron (SNP) | VAF 14/210 reads (7%) | catalogued as rs1467894472, COSV60137471; called by muse, mutect2
- VKORC1 | c.173+198C>T | Intron (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100161697, COSV100161818; called by muse, mutect2, varscan2
